Surgical pathology report (de-identified scan), TCGA case TCGA-E8-A436, project TCGA-THCA (Thyroid Carcinoma), tissue source site Asterand, specimen TCGA-E8-A436-01A (Primary Tumor).

Procurement Date: Laterality: Papillary carcinoma

Path Report: Tumor type: Papillary carcinoma

Tumor size: 2.5x2x1cm (right) 1.5x1x1cm (left)

Laterality: Bilateral ✓

Focality: Multifocal

Extrathyroidal extension: No

ICD-O-3

carcinoma, papillary, thyroid
8260/3

Site: thyroid, NOS
C73.9

8-3-12
eo

Source: NCI Genomic Data Commons file 7123bfa1-d0e9-4d56-9978-954adb1da29f (TCGA-E8-A436.0DE23F0B-79FC-49FF-86FE-E715BAC24B3A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).